Surgical pathology report (de-identified scan), TCGA case TCGA-PL-A8LY, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-PL-A8LY-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD-O-3
Carcinoma, infiltrating duct
Site @ Breast NOS 8500/3
C50.9
JW 5/19/14

1. **GROSS ASSESSMENT:** Cut section showed a variegated tumour measuring 3.4x2.5x1.5cm

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows a malignant tumour in cords, solid nests and tubular patterns. It is composed of large cells having moderately pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. The stroma is desmoplastic containing similar tumour cells and aggregates of lymphocytes. Focal areas of necrosis noted.

3. **Tumour Type:** Malignant
4. **Tumour Site:** Right Breast
5. **Distance of invasive carcinoma to closest margin:** -5mm
- **Which margin?** Deep resection

[page 2 of 2]
TSS Unique patient ID:

6. HISTOLOGICAL DIAGNOSIS: Invasive Ductal Carcinoma

7. COMMENTS:

Dr

Reporting Pathologist Name

Signature

Date

HM RA Discrepancy		☒
Brain Multiplicity History		☒
Unilateral/Synchronous Primary Breast		☒

Source: NCI Genomic Data Commons file 3741a2dd-a4a0-4ec0-903d-167c6494c5a8 (TCGA-PL-A8LY.8C97B391-96B4-468D-AAA3-24E196DE03CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).